Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5512, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5512-01A (Primary Tumor).

PATIENT HISTORY:

The patient has a history of PSA value of 6.14 ng/ml.

history of

The patient also has a

history of biopsy which reveals bilateral moderately differentiated prostatic adenocarcinoma.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical retropubic prostatectomy.

FINAL DIAGNOSIS:

TCGA - EJ - 5512

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN SEVEN LYMPH NODES EXAMINED (0/7).

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN SIX LYMPH NODES EXAMINED (0/6).

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE $3 + 4 = 7$.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.5 cm.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 25% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. THE CARCINOMA IS CLOSE (LESS THAN 0.1 CM) FROM THE POSTERIOR RIGHT MID CAPSULAR MARGIN (SLIDE 3T); HOWEVER ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 Mx.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC INFLAMMATION ARE NOTED.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 6.14
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	40.13gm
TUMOR SIZE:	Maximum dimension: 1.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	13
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMx
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file f2b328cf-508b-4f06-a263-5b205015c6c2 (TCGA-EJ-5512.8B273389-2655-4AC1-BCF0-B64505FE7B3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).